Somatic mutation profile of tumor specimen 0DLSYF from CCDI case PBBZWJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.1 years (1,502 days).
Specimen 0DLSYF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95aed8c5-cbab-4ef7-a7b3-ddc7f67abd29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLSXA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c312280-ef71-4198-a893-5e989ea69704

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIM3 | c.673T>C p.S225P | Missense Mutation (SNP) | VAF 180/397 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as rs765581135; called by muse, mutect2, varscan2
- RTL5 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 20/588 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.125); called by muse, mutect2
- TMEM94 | c.3152C>G p.P1051R | Missense Mutation (SNP) | VAF 41/635 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- P2RY8 | c.84G>C p.V28= | Silent (SNP) | VAF 56/524 reads (11%) | called by muse, mutect2, varscan2
- SLC35A2 | chrX:48911830 C>T | 5'Flank (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
